Gene-level copy-number profile of tumor specimen ALCH-B384-TTP1-A from ALCHEMIST case ALCH-B384, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.0 years (20,467 days).
Specimen ALCH-B384-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d50bbc4-8cc4-4b0f-9233-6401add89666.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B384-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/7a8af400-ddcc-4558-9718-ed6e14cae3c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 81; copy number 2: 57,974; copy number 3: 334; copy number 4: 3; copy number 5: 3; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,420,245–1,422,691, 1 gene, copy number 5 (within-gene range 3–5): AL391244.1.
- chr9:38,804,007–38,851,916, 1 gene, copy number 5: AL845311.1.
- chr11:89,895,799–89,900,449, 1 gene, copy number 5: AP005435.3.
- chr16:90,173,217–90,222,851, 1 gene, copy number 7 (within-gene range 2–7): LINC02193.

Autosomal genes at a single copy (total copy number 1): 70. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
